Surgical pathology report (de-identified scan), TCGA case TCGA-FP-A4BF, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FP-A4BF-01A (Primary Tumor).

[page 1 of 9]
Surg Path Final Report

* Final Report *

Result Type:
Result Date:
Result Status:
Result Title:
Verified By:
Encounter info:

SCANNED

*** Final Report ***

Final Diagnosis (Verified)

GE junction tumor, resection with frozen sections:

Invasive poorly differentiated adenocarcinoma with focal signet ring cell morphology and mucinous differentiation.

Maximal tumor diameter is 3.5 cm.

Tumor arises at GE junction and erodes through gastroesophageal wall to inked serosal/radial margin.

Metastatic adenocarcinoma in five (5) of 13 submitted perigastric/paraesophageal lymph nodes with additional nodular foci of tumor not clearly associated with nodal tissue.

Distal gastric margin is widely free of tumor.

Mediastinal lymph node, excision:

One (1) benign lymph node with no evidence of metastatic neoplasm.

Proximal margin of esophagus, resection:

Tumor focally present, however, proximal margin is free of tumor.

Tumor is grossly 1.2 cm from the proximal margin.

Mucosa at proximal margin demonstrates mild to moderate intraepithelial eosinophil infiltrate.

One (1) benign lymph node.

ICD-O-3
adenocarcinoma, signet ring cell
8490/3

site: gastroesophageal junction
C16.0

lu 4/26/12

Comment: AJCC pathologic stage: T3.N2.

Stage III B pg 130 AJCC Book

Signature Line

[page 2 of 9]
Surg Path Final Report

* Final Report *

Gross Description (Verified)

"FSA1." All frozen section control tissue is submitted in cassette "FSA1,".

"FSA2." All frozen section control tissue is submitted in cassette "FSA2,".

" " The specimen consists of a 3 cm portion of distal esophagus with an attached 5 cm in length x 14.2 cm in circumference portion of proximal stomach. The serosa is gray-pink. The specimen has previously been opened and there is a 3.5 x 3 cm firm red-tan ulcerated mass involving the gastroesophageal junction. The mass comes to within 4.2 cm of the distal surgical margin and may involve the proximal surgical margin. The distal surgical margin has been submitted for frozen section. The mass grossly appears to extend to the esophageal wall to a depth of 2 cm and grossly appears to abut the radial margin. The radial margin has been inked black. The remaining esophageal mucosa has a red-tan appearance. No additional areas of interest are identified in the esophagus. The gastric mucosa is red-tan and normal rugal folds are identified. No additional areas of interest are identified in the stomach. The attached fat is examined and 15 possible lymph nodes are identified. These range in size from 0.2 to 1.2 cm. "A1-A4," mass with adjacent radial margin; "A5-A8," lymph nodes.

"B, Mediastinal lymph nodes." The specimen consists of a 0.7 cm red-gray lymph node. "B," 2p, all.

"C, Esophagus distal end with staple." The specimen consists of a 2 cm portion of esophagus. The proximal margin is open. The distal margin has been closed with staples. The specimen is opened and there is a 1.7 x 1 cm red-tan ulcerated appearing area which abuts the distal surgical margin and comes to within 1.2 cm of the proximal margin. The remaining esophageal mucosa is gray-white and no additional areas of interest are grossly identified. The attached soft tissue is examined and 1 possible lymph node is identified. This measures 0.5 cm. "C1," proximal margin; "C2," ulcerated area at distal margin; "C3," lymph node.

Received for research purposes is 1 yellow cassette labeled "

and 1 green cassette labeled "

Signature Line

Frozen Section Diagnosis (Verified)

Clinical History: Tumor at G.E.J./distal esophagus.

Gross A: Mucosa and gastric wall at distal margin is grossly unremarkable. Jelly roll of distal mucosal margin submitted for frozen section in 2

[page 3 of 9]
Surg Path Final Report

* Final Report *

cassettes. Barrett's mucosa involves proximal margin (not free surgical margin of the esophagus since more of the esophagus will be resected). Specimen opened and reviewed intraoperatively with surgeons. GEJ is serially sectioned and a small sample of tumor is harvested for tumor study (patient consent previously obtained). Nonneoplastic gastric tissue is also submitted for further study.

FAS1 and FSA2, distal surgical margin: No tumor identified.

Clinical Information (Verified)

Adenocarcinoma of the gastroesophageal junction.

Completed Action List:

[page 4 of 9]
GI Final Report

* Final Report *

Result Type:
Result Date:
Result Status:
Result Title:
Verified By:
Encounter info:

* Final Report *

Final Diagnosis (Verified)

Gastroesophageal junction mass, endoscopic biopsy:

MUCINOUS ADENOCARCINOMA.

- SISH (silver in situ hybridization) study to evaluate for HER2/neu overexpression by the tumor has been ordered, the results to be reported in an addendum.

Esophagus, endoscopic biopsy:

Squamous mucosa with a mild intraepithelial eosinophilic infiltrate and marked reactive changes. Also present are detached fragments of necrotic squamous mucosa, morphologically suggestive of esophagitis dissecans superficialis. One fragment contains several eosinophils and eosinophilic microabscesses.

- Likely secondary to stricture of GEJ by neoplasm.
- No viral inclusions or fungal organisms are conspicuous by routine histology.
- No dysplasia or malignancy is identified.

Signature Line

Gross Description (Verified)

"A, GE junction." The specimen consists of multiple tan-gray 2-4 mm friable fragments. "A," fragments, all.

"B, Esophagus." The specimen consists of 4 thin, flat, white, friable 2-5 mm fragments. "B," 4p, all, tea bag.

[page 5 of 9]
GI Final Report

* Final Report *

Signature Line

Clinical Information (Verified)

GI bleed. Ulcerated mass at GE junction – suspect severe esophagitis proximal to malignancy up to mid esophagus.

Specimens:

- 1. GE junction ulcerated mass.
- 2. Severe esophagitis.

Completed Action List:

[page 6 of 9]
Addendum Report Surgical

* Final Report *

Result Type:

Result Date:

Result Status:

Result Title:

Verified By:

Encounter Info:

*** Final Report ***

Addendum (Verified)

HER2/neu Immunohistochemical Study with Digital Image Analysis

Specimen: Adenocarcinoma of the gastroesophageal junction, tissue block

Method: Immunoperoxidase study for HER2/neu antigen was performed on formalin-fixed, paraffin-embedded tissue and submitted for digital image analysis. Digital image analysis was performed at 200x power using the _____ system. The areas demonstrating the most reactivity were evaluated.

RESULTS: Negative for HER2/neu overexpression by immunohistochemistry, as analyzed by digital image analysis.

Signature Line

Completed Action List:

[page 7 of 9]
Addendum Report Surgical

* Final Report *

[page 8 of 9]
Addendum Report Surgical

* Final Report *

Result Type:
Result Date:
Result Status:
Result Title:
Verified By:
Encounter info:

*** Final Report ***

Addendum (Verified)

HER2 Gene Amplification Study by SISH

Specimen: Adenocarcinoma of the gastroesophageal junction, tissue block

Control: Internal control.

Method: Silver in situ hybridization technology (SISH) is employed on formalin-fixed, paraffin-embedded tissue to detect copies of the HER2 gene and chromosome 17 within the tumor. The HER2 gene signals in a minimum of 20 interphase nuclei are counted within the area of the tumor demonstrating the highest HER2 signal and compared to counts of chromosomal 17 signals within the same area. Results are expressed as the ratio of HER2 signals as compared to chromosome 17 signals.

Results: SISH assay demonstrated a HER2 to chromosome 17 ratio of 1.2. This result does not meet criteria for HER2 amplification.

Reference ranges: For gastroesophageal tumors, a HER2/chromosome 17 ratio of ≥ 2.0 is considered positive for HER2 amplification, a HER2/chromosome 17 ratio of < 2.0 and ≥ 1.8 is considered equivocal for HER2 amplification, and a HER2/chromosome 17 ratio of < 1.8 is considered negative (not amplified) for HER2 amplification.

Interpretation: SISH-negative for HER2 amplification. See Comment.

Comment: Rare cases may not show HER2 gene amplification but have HER2 protein overexpression demonstrated by immunohistochemistry. The clinical significance of HER2 protein overexpression in the absence of HER2 gene amplification is unclear; however, these patients may be candidates for trastuzumab treatment. As such, specimens that do not show HER2 gene amplification by in situ hybridization are submitted for immunohistochemical (IHC) analysis for HER2 protein overexpression. Result of IHC analysis will be reported in a separate addendum.

General Comment: SISH (silver in situ hybridization) is highly concordant to FISH (fluorescence in situ hybridization) for chromogenetic detection of HER2. FISH is a cytogenetic method that detects DNA sequences using fluorescent probes. SISH is a cytogenetic method that detects DNA sequences using silver probes. Fluorescence probes degenerate rapidly at room temperature, and fluorescence in situ hybridization signals fade after a few weeks. The stability of the silver probes allows slide storage at room temperature. FISH and SISH assays for HER2 amplification should be used as an adjunct to existing clinical and pathologic information.

[page 9 of 9]
Addendum Report Surgical

* Final Report *

Signature Line

Completed Action List:

Alpha Discrepancy		
Tumor Malignancy History		
Site is (R/L) U/L		

8/24/12

Source: NCI Genomic Data Commons file 3b258e51-f4a0-4570-86b4-591142bd72d4 (TCGA-FP-A4BF.81AA61B1-8B3F-405F-96DC-E6CA5A05216A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).